Surgical pathology report (de-identified scan), TCGA case TCGA-DH-A7UR, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-A7UR-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation / Department of Pathology

Case Type:

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Brain tumor

A. Frozen Section Charge

B. Brain tumor

B. KI-67, Nuclear Antigen, Mib1

B. Glial Fibrill. Acid Prt

B. 1P19q Malignant Glioma Anaysis

B. 1P19q Malignant Glioma Analysis, add x 3

CLINICAL HISTORY: old female with severe head pain , CT and MRI were done; revealed right medial frontal lobe lesion consistent with a low grade brain tumor.

GROSS DESCRIPTION: Received the following specimens in the

, labeled with the patient's name and hospital #:

A. Brain tumor

B. Brain tumor

A. The specimen is received fresh designated "brain tumor" and consists of a 0.6 x 0.6 x 0.4 cm portion of tan to beige soft tissue pieces. A representative portion is submitted for frozen section. Frozen section diagnosis is "Infiltrating glioma with oligodendroglioma-like features" per The frozen tissue is submitted in cassette FSA1. The remaining tissue is submitted in cassette A2.

B. The specimen is received fresh designated "brain tumor" and consists of a 1.9 x 1.5 x 0.8 cm beige to gray-tan soft tissue pieces. A representative portion is submitted to the and the

ICD-O-3

Oligodendroglioma, grade III
9451/3

Site ^{CSCF} Brain, supratentorial NOS
@ 71.0

Path
Brain NOS
@ 71.9

9/10/4/13

PUTSS,
No surgery or tx since
pt. followed w/ scans only.
BCR

[page 2 of 3]
remaining tissue is submitted in cassette B1.

DIAGNOSIS:

A. "Brain tumor":

Anaplastic oligodendroglioma (WHO Grade III)

B. "Brain tumor":

Anaplastic oligodendroglioma (WHO Grade III) (see comment)

COMMENT: This highly infiltrative glioma shows an overall uniform histology with tumor cells having classic perinuclear haloes and chicken-wire-like background capillaries. There are also areas of increased cellularity with mitoses. The tumor extensively infiltrates the cerebral cortex with prominent subpial and perineuronal accumulations of neoplastic cells. The Ki-67 labeling index is 15-20%. A few scattered cells are immunoreactive for GFAP while the majority of the tumor is negative. These results support the diagnosis. Molecular analysis for chromosomes 1p and 19q will be performed and reported as an addendum to this report.

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Note: Test systems have been developed and their performance characteristics determined by Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be

[page 3 of 3]
regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Pathologist

HPA Discrepancy		✓

Source: NCI Genomic Data Commons file d2143be8-6252-4797-bd58-03887fe01677 (TCGA-DH-A7UR.F563DFEE-08E2-48B2-904D-EA5E3DEF6628.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).